Somatic mutation profile of tumor specimen TCGA-LN-A7HZ-01A (aliquot TCGA-LN-A7HZ-01A-31D-A351-09) from TCGA case TCGA-LN-A7HZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 49.1 years (17,931 days).
Specimen TCGA-LN-A7HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b3b657f-9b20-4576-b716-afee51b5fe41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A7HZ-10A (Blood Derived Normal), aliquot TCGA-LN-A7HZ-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89bf6dde-8ec4-4361-b963-4646c1478569

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 54/108 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.658T>G p.Y220D | Missense Mutation (SNP) | VAF 57/75 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4094G>A p.R1365H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748021201, COSV100622180; called by muse, mutect2, varscan2
- CCN2 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.753); catalogued as COSV63466848; called by muse, mutect2, varscan2
- DAZAP2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV101199391; called by muse, mutect2, varscan2
- EXO1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.635); catalogued as COSV100800104, COSV62220764; called by muse, mutect2, varscan2
- FNDC1 | c.1555del p.A519Rfs*48 | Frame Shift Del (DEL) | VAF 31/63 reads (49%) | catalogued as COSV51940579; called by mutect2, pindel, varscan2
- IQSEC1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771164485, COSV56222733; called by muse, mutect2, varscan2
- KMT2C | c.1737G>A p.A579= | Splice Region (SNP) | VAF 22/79 reads (28%) | catalogued as rs1317991358; called by muse, mutect2, varscan2
- MBL2 | c.95G>T p.C32F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199957742; called by muse, mutect2, varscan2
- MYH13 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1311955222; called by muse, mutect2, varscan2
- OPN4 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1423400249; called by muse, mutect2, varscan2
- OPRPN | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV101271076, COSV68192548; called by muse, mutect2, varscan2
- RSPH10B2 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs998825683; called by muse, mutect2
- RYR2 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 76/94 reads (81%) | catalogued as rs1340830020, COSV100773556; called by muse, mutect2, varscan2
- TPCN1 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1351672343; called by muse, mutect2, varscan2
- TRPC7 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274493309, COSV61452394; called by muse, mutect2, varscan2
- TTN | c.15225G>C p.K5075N (on ENST00000591111; = p.K4148N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60376643; called by muse, mutect2, varscan2
- USP14 | c.1025A>G p.K342R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs917801705; called by muse, mutect2, varscan2
- ZNF646 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1460730157, COSV56218717; called by muse, mutect2, varscan2
- ZNF93 | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs879188185, COSV104416048; called by muse, mutect2, varscan2
- ADAMTS20 | c.2515A>G p.I839V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AFF3 | c.2746A>G p.K916E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANKDD1A | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP10D | c.2300T>G p.L767R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CC2D1A | c.1849A>C p.K617Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3803T>C p.V1268A | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- COL20A1 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DOT1L | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DSCAM | c.5663C>T p.A1888V | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- F5 | c.1855A>C p.N619H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- FBXO34 | c.2084A>T p.N695I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FLG | c.10513C>T p.H3505Y | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FOXF1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCTD19 | c.2611A>G p.I871V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.6183G>A p.L2061= | Splice Region (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- MAGI2 | c.3064G>C p.E1022Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYLK | c.4894G>T p.V1632L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OPRPN | c.159T>A p.Y53* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- OTUD7A | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAPGEF2 | c.1727T>G p.L576W | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RCCD1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX6 | c.1334A>G p.Q445R (on ENST00000528429 / NM_001145819.2; = p.Q404R on NM_017508.3) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TGFBR2 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAC2 | c.55del p.L19Ffs*39 (on ENST00000403766 / NM_001144072.2; = p.F61Sfs*25 on NM_177967.4) | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- USH2A | c.11788G>C p.D3930H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.253); called by muse, mutect2
- ZNF440 | c.668C>G p.T223S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF496 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FBXL4 | c.1722G>C p.P574= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV57750481; called by muse, mutect2, varscan2
- LHFPL5 | c.225C>T p.S75= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs541264130; called by muse, mutect2, varscan2
- MAPK3 | c.594C>T p.T198= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs542338052, COSV53773556; called by muse, mutect2, varscan2
- MDM1 | c.468C>A p.T156= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- MED1 | c.1617C>T p.N539= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- MGAM | c.87T>C p.V29= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- NLRP14 | c.339A>G p.Q113= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1032333222, COSV55072832; called by muse, mutect2, varscan2
- SLC25A41 | c.87C>T p.A29= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- TBX15 | c.1794C>T p.S598= (on ENST00000369429 / NM_001330677.2; = p.S492= on NM_152380.3) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs940764815; called by muse, varscan2
- TRIM37 | c.1779C>T p.S593= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- TRIM71 | c.1536C>T p.H512= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs767735062; called by muse, varscan2
- VTI1A | c.141A>G p.E47= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1367923521; called by muse, mutect2, varscan2
- XAB2 | c.2313G>T p.L771= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- ZWINT | c.768G>A p.G256= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- PABPC4 | c.972+355G>T | Intron (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
